Somatic mutation profile of tumor specimen TCGA-J2-8194-01A (aliquot TCGA-J2-8194-01A-11D-2238-08) from TCGA case TCGA-J2-8194, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.7 years (25,441 days).
Specimen TCGA-J2-8194-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c3e48d3-618b-40d3-a9c7-bc98a3bd226f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J2-8194-10A (Blood Derived Normal), aliquot TCGA-J2-8194-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f7e6a62-368b-4354-8a5c-6cf515aef2f0

The open-access MAF lists 161 somatic variants for this specimen: 123 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 34, Nonsense Mutation 7, RNA 2, Intron 2, Splice Site 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG5 | c.1888T>C p.F630L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV53182342; called by muse, mutect2, varscan2
- ADAMTS12 | c.3582G>T p.M1194I | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV61256359; called by muse, mutect2, varscan2
- ADAMTS2 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1240220055, COSV51072365; called by muse, mutect2, varscan2
- ALOX5 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs551364951, COSV65551176; called by muse, mutect2, varscan2
- ARHGAP28 | c.662C>G p.T221S (on ENST00000383472 / NM_001366230.1; = p.T62S on NM_001010000.3) | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV51632053; called by muse, mutect2, varscan2
- ARMC9 | c.1685A>T p.Q562L | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63019533; called by muse, mutect2, varscan2
- ASPM | c.8803A>G p.S2935G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as COSV54125283; called by muse, mutect2
- ATRNL1 | c.522T>A p.N174K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61797849; called by muse, mutect2, varscan2
- ATXN2L | c.2267C>T p.S756L | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1359651710, COSV100295096; called by muse, mutect2, varscan2
- BEND3 | c.2032G>T p.E678* | Nonsense Mutation (SNP) | VAF 32/65 reads (49%) | catalogued as COSV64680111; called by muse, mutect2, varscan2
- BOLA1 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV64966456; called by muse, mutect2, varscan2
- CACNA1I | c.3602G>A p.R1201H | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60801902; called by muse, mutect2, varscan2
- CACNA2D3 | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 75/414 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55517238; called by muse, mutect2, varscan2
- CBR4 | c.535+1G>T p.X179_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100085880; called by muse, varscan2
- CBR4 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100085881; called by muse, mutect2, varscan2
- CCDC39 | c.2058C>A p.N686K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV56479248; called by muse, mutect2, varscan2
- CCNB3 | c.2543C>G p.P848R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.216); catalogued as COSV52070209; called by muse, mutect2
- CHAF1B | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761186456, COSV58439294, COSV58441094; called by muse, mutect2, varscan2
- CHST1 | c.1192T>A p.S398T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV57321975; called by muse, mutect2, varscan2
- CLCA2 | c.2607G>T p.M869I | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV65286234; called by muse, mutect2, varscan2
- CNGA2 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 88/334 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs771830593, COSV61703385; called by muse, mutect2, varscan2
- COL11A1 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62174058; called by muse, mutect2, varscan2
- COL7A1 | c.4004G>A p.G1335E | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100097579; called by muse, mutect2, varscan2
- CPEB3 | c.1312C>A p.R438S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV56453872; called by muse, mutect2, varscan2
- CRX | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.071); catalogued as COSV55757179; called by muse, mutect2, varscan2
- CSF1R | c.1061C>A p.A354D | Missense Mutation (SNP) | VAF 88/269 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV53829510; called by muse, mutect2, varscan2
- CSMD3 | c.4843G>T p.D1615Y (on ENST00000297405 / NM_001363185.1; = p.D1511Y on NM_052900.3) | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1243600702, COSV52110725, COSV52123721; called by muse, mutect2, varscan2
- DDIAS | c.1178C>G p.P393R | Missense Mutation (SNP) | VAF 129/359 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.483); catalogued as COSV61271576; called by muse, mutect2, varscan2
- DMD | c.7282G>C p.A2428P | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.394); catalogued as COSV58893716; called by muse, mutect2, varscan2
- DNAH1 | c.6619G>A p.V2207M | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs778924881, COSV70226775; called by muse, mutect2, varscan2
- DNAJC7 | c.1055A>T p.E352V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57267985; called by muse, mutect2, varscan2
- DRP2 | c.2114+1G>C p.X705_splice | Splice Site (SNP) | VAF 14/107 reads (13%) | catalogued as COSV65809342, COSV65810428; called by muse, mutect2, varscan2
- DSEL | c.3213G>C p.L1071F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV59489618, COSV59493874; called by muse, mutect2, varscan2
- EHD3 | c.1448A>T p.K483M | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59029353; called by muse, mutect2, varscan2
- ELMO1 | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1323952793, COSV60296379; called by muse, mutect2, varscan2
- EPHA3 | c.1705G>T p.G569C | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV60695343; called by muse, mutect2, varscan2
- EPHA6 | c.2209G>T p.G737* (on ENST00000389672 / NM_001080448.3; = p.G129* on NM_173655.4) | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV101065312; called by muse, mutect2, varscan2
- ERCC3 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV53425743; called by muse, mutect2, varscan2
- FAM234A | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.224); catalogued as rs376511500, COSV56995186; called by muse, mutect2, varscan2
- FAP | c.160T>A p.Y54N | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.877); catalogued as COSV51859533; called by muse, mutect2, varscan2
- FOXC1 | c.534C>G p.D178E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV66515650; called by muse, mutect2, varscan2
- FTHL17 | c.112A>T p.M38L | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV100784400; called by muse, mutect2, varscan2
- FUT11 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1006205780, COSV59540175; called by muse, mutect2, varscan2
- GCLC | c.371G>A p.R124Q (on ENST00000643939; = p.R128Q on NM_001498.4) | Missense Mutation (SNP) | VAF 53/447 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774839188, COSV57593772; called by muse, mutect2, varscan2
- GLI2 | c.1834G>A p.E612K (on ENST00000361492 / NM_001374353.1; = p.E629K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as rs387907277, CM109720, COSV58035328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPATCH2 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV65127352; called by muse, mutect2, varscan2
- GRIK2 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.837); catalogued as rs148565717; called by muse, mutect2, varscan2
- HAX1 | c.195C>G p.F65L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV55168283; called by muse, mutect2, varscan2
- HMGCLL1 | c.250G>T p.G84W | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51440930; called by muse, mutect2, varscan2
- ITSN1 | c.4256A>T p.Q1419L | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV67156875; called by muse, mutect2, varscan2
- KLHL18 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775179182, COSV51744203; called by muse, mutect2, varscan2
- LAPTM5 | c.558G>C p.K186N | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV53852481, COSV53854455; called by muse, mutect2, varscan2
- LRFN3 | c.96C>A p.C32* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV55817029; called by muse, mutect2, varscan2
- LUZP2 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61196436; called by muse, mutect2, varscan2
- MAML3 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV59071597; called by mutect2, varscan2
- MAP3K7 | c.1313G>T p.R438I (on ENST00000369329 / NM_145331.3; = p.R411I on NM_003188.4) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.527); catalogued as COSV65223648; called by muse, mutect2, varscan2
- MARVELD2 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432208441, COSV57779568; called by muse, mutect2, varscan2
- MED12 | c.4384C>T p.R1462C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV61332851; called by muse, mutect2
- MEFV | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV54818801; called by muse, mutect2
- MEGF6 | c.863A>T p.E288V | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53886712; called by muse, mutect2, varscan2
- MORC4 | c.1385G>A p.R462K | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV55239731, COSV99717476; called by muse, mutect2, varscan2
- MTMR8 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV66392510; called by muse, varscan2
- MUC16 | c.25494G>T p.E8498D | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV67447597; called by muse, mutect2, varscan2
- MYO3B | c.2575G>T p.D859Y | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100508748, COSV58695517; called by muse, mutect2, varscan2
- NALCN | c.4548C>A p.C1516* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as COSV51919996; called by muse, mutect2, varscan2
- NCOA3 | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1293535053, COSV59066039; called by muse, mutect2, varscan2
- NLRP5 | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV66762327, COSV66765072; called by muse, mutect2, varscan2
- OR3A1 | c.239C>G p.T80S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as COSV60162572; called by muse, mutect2, varscan2
- OR51V1 | c.233T>A p.L78Q | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58314241; called by muse, mutect2, varscan2
- OVCH1 | c.2858G>T p.S953I | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV58959978; called by muse, mutect2, varscan2
- PAMR1 | c.2073G>A p.W691* (on ENST00000619888 / NM_001001991.3; = p.W708* on NM_015430.4) | Nonsense Mutation (SNP) | VAF 24/120 reads (20%) | catalogued as COSV53509928; called by muse, mutect2, varscan2
- PARP4 | c.1796A>G p.Q599R | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.702); catalogued as rs1239861567, COSV67960687; called by muse, mutect2, varscan2
- PCDH19 | c.893T>G p.V298G | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55258206; called by muse, mutect2
- PCDHB16 | c.495T>A p.N165K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53358350, COSV53372899; called by muse, mutect2, varscan2
- PEG3 | c.1975G>A p.G659S | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.056); catalogued as COSV55626099; called by muse, mutect2, varscan2
- PFKL | c.850G>T p.V284F | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV62462703; called by muse, mutect2, varscan2
- PKP2 | c.1932T>A p.S644R | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV50726268; called by muse, mutect2, varscan2
- PNPLA6 | c.1792G>A p.A598T (on ENST00000414982 / NM_001166111.2; = p.A550T on NM_006702.5) | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs772343586, COSV55374253; called by muse, mutect2, varscan2
- PPP3CA | c.1439A>T p.N480I | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59919947; called by muse, mutect2, varscan2
- PRR16 | c.496A>T p.I166F (on ENST00000407149 / NM_001300783.2; = p.I143F on NM_016644.2) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV65395111; called by muse, mutect2, varscan2
- PRSS38 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64539727, COSV64540813; called by muse, mutect2, varscan2
- PRX | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52527860; called by muse, mutect2, varscan2
- RBM22 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV52270539; called by muse, mutect2, varscan2
- RC3H2 | c.1918A>T p.N640Y | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.193); catalogued as COSV61798660; called by muse, mutect2
- RPA1 | c.1442G>T p.C481F | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54607371; called by muse, mutect2, varscan2
- RTL9 | c.3122C>G p.P1041R | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV71825419; called by muse, mutect2, varscan2
- RTN1 | c.518C>A p.A173E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV50719125; called by muse, mutect2, varscan2
- RYR3 | c.9334G>A p.E3112K (on ENST00000389232; = p.E3113K on NM_001036.6) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV66779203; called by muse, mutect2, varscan2
- SATB1 | c.2086C>A p.Q696K | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58667733; called by muse, mutect2, varscan2
- SELP | c.88A>T p.I30F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV55248686; called by muse, mutect2, varscan2
- SH3BP4 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60642516; called by muse, mutect2, varscan2
- SH3KBP1 | c.107G>T p.W36L | Missense Mutation (SNP) | VAF 96/406 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65639416; called by muse, mutect2, varscan2
- SHCBP1L | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62353507; called by muse, mutect2, varscan2
- SLC26A7 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.253); catalogued as COSV52586992; called by muse, mutect2, varscan2
- SLC28A1 | c.861G>T p.Q287H | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54476778; called by muse, mutect2, varscan2
- SPP2 | c.73T>A p.W25R | Missense Mutation (SNP) | VAF 80/269 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV51444496; called by muse, mutect2, varscan2
- ST7 | c.1228G>T p.V410L (on ENST00000265437 / NM_021908.3; = p.V387L on NM_018412.4) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV55380635; called by muse, mutect2, varscan2
- STK11 | c.436A>T p.K146* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as CD041178, COSV58820800; called by muse, mutect2, varscan2
- TANC1 | c.2360G>T p.G787V | Missense Mutation (SNP) | VAF 101/396 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as COSV55083642; called by muse, mutect2, varscan2
- TBCD | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV62797981; called by muse, mutect2, varscan2
- TEX13A | c.998C>A p.P333H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.306); catalogued as COSV61144038; called by muse, varscan2
- TLR10 | c.802C>A p.H268N | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV58299255; called by muse, mutect2, varscan2
- TLR5 | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as rs769787865, COSV60558000; called by muse, mutect2, varscan2
- TRBV24-1 | c.269A>G p.Q90R | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs753713986; called by muse, mutect2, varscan2
- TRERF1 | c.3338A>T p.E1113V | Missense Mutation (SNP) | VAF 441/964 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61667599; called by muse, mutect2, varscan2
- TRERF1 | c.316A>G p.M106V | Missense Mutation (SNP) | VAF 63/548 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.035); catalogued as rs781192866, COSV61667618; called by muse, mutect2, varscan2
- TRIM56 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60157335; called by muse, mutect2, varscan2
- TRO | c.3503G>A p.C1168Y | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV51498079; called by muse, varscan2
- TSPAN12 | c.77T>G p.I26S | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV56078615; called by muse, mutect2, varscan2
- TTC8 | c.278G>T p.G93V (on ENST00000338104 / NM_001288781.1; = p.G103V on NM_144596.4) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs140710339; called by muse, mutect2, varscan2
- USP51 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.119); catalogued as rs1343441550, COSV72351498; called by muse, mutect2, varscan2
- WDR59 | c.2717G>A p.R906Q | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.689); catalogued as rs144948949; called by muse, mutect2, varscan2
- WWC3 | c.3127G>T p.E1043* | Nonsense Mutation (SNP) | VAF 37/157 reads (24%) | catalogued as COSV66501726; called by muse, mutect2, varscan2
- XRCC1 | c.976G>T p.V326L | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV53447392; called by muse, mutect2, varscan2
- ZFHX4 | c.3250C>A p.Q1084K | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV50520484; called by muse, mutect2, varscan2
- ZNF226 | c.1816T>C p.C606R | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as COSV56195994; called by muse, mutect2, varscan2
- ZNF536 | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1431241819, COSV62819204; called by muse, mutect2, varscan2
- ZP4 | c.509G>A p.C170Y | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63911026; called by muse, mutect2, varscan2
- ZPLD1 | c.70T>C p.Y24H (on ENST00000466937 / NM_001329788.1; = p.Y40H on NM_175056.2) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as COSV60352022; called by muse, mutect2
- ADAMTS13 | c.3702del p.N1235Tfs*26 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- GCN1 | c.6167_6169del p.E2056del | In Frame Del (DEL) | VAF 18/110 reads (16%) | called by pindel, varscan2
- KEAP1 | c.1618_1622del p.E540Rfs*32 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- AKNA | c.2031C>T p.S677= | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as rs1394611046, COSV56311184; called by muse, mutect2, varscan2
- ASB9 | c.87G>A p.L29= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV66851340; called by muse, mutect2, varscan2
- CACNG4 | c.720A>T p.R240= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV50924205; called by muse, mutect2, varscan2
- CDH13 | c.1260C>T p.N420= | Silent (SNP) | VAF 45/270 reads (17%) | catalogued as rs779129520, COSV51794527; called by muse, mutect2, varscan2
- CHIC1 | c.234G>A p.E78= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs1388837332, COSV65155818; called by muse, mutect2
- COL4A1 | c.162G>T p.P54= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV65421915; called by muse, mutect2, varscan2
- CRYBG2 | c.3477C>T p.C1159= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV57483973; called by muse, mutect2, varscan2
- EDEM3 | c.313C>T p.L105= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV58922223; called by muse, mutect2
- FAT4 | c.5358T>C p.S1786= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as COSV58673069; called by muse, mutect2, varscan2
- FTHL17 | c.111T>G p.S37= | Silent (SNP) | VAF 43/175 reads (25%) | catalogued as COSV100784402; called by muse, mutect2, varscan2
- GLI3 | c.480C>T p.S160= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs148660482; ClinVar: likely benign; called by muse, mutect2
- GNL3L | c.291G>A p.E97= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV100328123, COSV60575482; called by muse, mutect2, varscan2
- H2BU1 | c.321G>T p.L107= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV64209596; called by muse, mutect2, varscan2
- ITGB4 | c.2241G>A p.P747= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as rs377428995, COSV52329813; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF4B | c.51C>A p.R17= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as rs1265233762, COSV70528062; called by muse, mutect2, varscan2
- LRRC7 | c.4285C>A p.R1429= (on ENST00000651989 / NM_001370785.2; = p.R1349= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV50414746; called by muse, mutect2, varscan2
- MYH13 | c.2964A>T p.A988= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV52821623; called by muse, mutect2
- NADSYN1 | c.1977C>T p.A659= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as rs143948838, COSV59810457; called by muse, mutect2, varscan2
- NID1 | c.2832C>A p.T944= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV51615338; called by muse, mutect2, varscan2
- OBSCN | c.3330T>C p.D1110= | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as rs371731852; called by muse, mutect2, varscan2
- OR52L1 | c.834C>T p.L278= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV59985835; called by muse, mutect2, varscan2
- PARPBP | c.1149C>T p.I383= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV59671829, COSV59676978; called by muse, mutect2, varscan2
- PCDHB16 | c.1683G>T p.V561= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV53358357; called by muse, mutect2, varscan2
- PITPNB | c.45T>C p.V15= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV58060619; called by muse, mutect2
- RBL1 | c.1413A>T p.I471= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV60328510; called by muse, mutect2, varscan2
- RNF139 | c.1647C>T p.I549= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV52677876; called by muse, mutect2, varscan2
- SHANK3 | c.4434G>T p.G1478= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV53183924, COSV53188002; called by muse, mutect2, varscan2
- SLITRK4 | c.1833T>G p.P611= | Silent (SNP) | VAF 48/164 reads (29%) | catalogued as COSV62022324; called by muse, mutect2, varscan2
- SORCS1 | c.1017G>A p.V339= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as COSV53844364; called by muse, mutect2, varscan2
- STRN4 | c.1365C>T p.T455= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs770370239, COSV54416379; called by muse, varscan2
- TLR7 | c.3123T>C p.Y1041= | Silent (SNP) | VAF 60/288 reads (21%) | catalogued as COSV66123612; called by muse, mutect2, varscan2
- TRAV8-6 | c.340G>C p.*114= | Silent (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- USH2A | c.187C>A p.R63= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs781223647, CM001804, COSV100240460, COSV56332304; called by muse, mutect2, varscan2
- ZNF835 | c.936C>A p.G312= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV73379206, COSV73379497; called by muse, mutect2
- C14orf177 | n.459A>G | RNA (SNP) | VAF 24/56 reads (43%) | catalogued as COSV57900392; called by muse, mutect2, varscan2
- C1orf220 | n.551G>T | RNA (SNP) | VAF 25/114 reads (22%) | catalogued as rs145009184; called by muse, mutect2, varscan2
- UROC1 | c.903-632G>A | Intron (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99332297; called by muse, mutect2, varscan2
- USH1C | c.1284+7587C>A | Intron (SNP) | VAF 23/134 reads (17%) | catalogued as COSV99141854; called by muse, mutect2, varscan2
